Surgical pathology report (de-identified scan), TCGA case TCGA-23-1809, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1809-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

**EXPLORATORY LAPARATOMY, TOTAL ABDOMINAL HYSTERECTOMY WITH
BILATERAL SALPINGO-OOPHORECTOMY**

A. RIGHT TUBE AND OVARY (FROZEN)

- Müllerian adenocarcinoma, serous type, extensively involving ovary
- Size: 7.0 cm approximately, in greatest dimension
- Capsule: Ruptured
- Angiolymphatic invasion: Not identified
- Necrosis: Present, accounting for approximately 15% of tumor volume
- Portion of fallopian tube with no carcinoma identified
- AJCC Pathologic Stage (2002, 6th Ed): pT2c/N0

B. PELVIC SIDE TUMOR RIGHT

- Involved by high grade müllerian adenocarcinoma, serous type

C. RIGHT TUMOR SAMPLE #1 (FOR TCGA STUDY)

- High grade müllerian adenocarcinoma, serous type
- Necrosis: 10%
- Tumor cell nuclei: 85%

D. RIGHT OVARIAN TUMOR SAMPLE #

- High grade müllerian adenocarcinoma, serous type
- Necrosis: 5%
- Tumor cell nuclei: 80%

E. RIGHT OVARIAN TUMOR SAMPLE #3

- High grade müllerian adenocarcinoma, serous type
- Necrosis: 20%
- Tumor cell nuclei: 80%

F. LEFT TUBE AND OVARY

- Müllerian adenocarcinoma, serous type, focally involving surface and underlying ovarian parenchyma
- Size: 5.0 mm approximately
- Capsule: Intact
- Angiolymphatic invasion: Not identified
- Necrosis: Present
- Portion of fallopian tube with atypical epithelial hyperplasia and detached fragment in the tubal lumen; no direct invasion or in situ carcinoma

G. RIGHT PERIAORTIC LYMPH NODE

PATIENT NOTIFIED OF RESULTS
DR: NURSE: DATE:

[page 2 of 4]
- Five lymph nodes with no carcinoma identified (5)

H. UTERUS AND CERVIX

- Cervix with squamous metaplasia and reactive change
- Inactive endometrium
- Myometrium and serosa with no significant pathologic change
- No carcinoma identified

I. RIGHT PELVIC LYMPH NODE

- Two lymph nodes with no carcinoma identified

J, K, L. OMENTUM PART 1, 2, and 3

- No carcinoma identified
- One benign lymph node (1)

HISTORY: Pelvic mass

MICROSCOPIC:

See diagnosis.

GROSS:

A. RIGHT TUBE AND OVARY (FROZEN)

Labeled with patient's name, "right tube and ovary", and received fresh in the Operating Room for frozen section and subsequently fixed in formalin is a 142 gram, oophorectomy specimen. The ovary is 7.5 x 6.0 x 5.5 cm. One portion of fallopian tube is identified, which appears grossly uninvolved by tumor.

The ovary is subtotally replaced by a cystic and solid neoplasm that is approximately 7.0 x 6.0 x 5.5 cm. The capsule is partially ruptured over an area with papillary protrusion that measures 2.5 x 1.5 x 0.5 cm. The tumor is tan-yellow, firm, and mostly solid mass. There is a focal gray, gelatinous portion of tumor that measures 1.7 x 1.5 x 0.8 cm. Sectioning reveals focal areas of necrosis and hemorrhage. No other lesion is identified.

Ink key: Black - external surface

Slide key:

- A1. Frozen section remnant - 2
- A2, A3. Tumor to ovary and possibly fallopian tube - 2, 1
- A4. Fallopian tube - 2
- A5. Tumor with gelatinous area - 1
- A6. Tumor protruding out of the capsule - 1
- A7. Additional tumor - 3
- A8-A10. Additional tumor - 1 each

Additional note from the Operating Room: "Right ovarian tumor was stuck to pelvic side wall and ruptured upon removal. There is papillary tumor on the external aspect of the ovary."

B. PELVIC SIDE TUMOR RIGHT

Labeled with patient's name, labeled "pelvic side tumor right", and received in formalin are two portions of fibrofatty tissue measuring 4.0 x 3.0 x 1.2 cm, and 3.0 x 1.2 x 0.3 cm. The larger portion has irregular black-purple side and the other side is covered by fat. The smaller portion has yellow-tan color with irregular surface. Entirely submitted.

Slide key:

- B1. Smaller portion of tissue and one fragment of the larger tissue - 2
- B2, B3. The larger portion of tissue - 3, 2

[page 3 of 4]
C. RIGHT TUMOR SAMPLE #1 (FOR [REDACTED])

Labeled with patient's name, labeled "right ovarian tumor sample #1", and received in formalin are two portions of firm, yellow tumor measuring 1.0 x 0.3 x 0.2 cm, and 0.6 x 0.5 x 0.4 cm. Entirely submitted.

Slide key:

C1. 2

D. RIGHT OVARIAN TUMOR SAMPLE #2 [REDACTED]

Labeled with patient's name, labeled "right ovarian tumor sample #2", and received in formalin are two portions of firm, yellow tumor measuring 0.9 x 0.6 x 0.3 cm, and 0.8 x 0.5 x 0.3 cm. Entirely submitted.

Slide key:

D1. 2

E. RIGHT OVARIAN TUMOR SAMPLE #3 [REDACTED]

Labeled with patient's name, labeled "right ovarian tumor sample #3", and received in formalin are two portions of firm, yellow tumor measuring 1.2 x 0.4 x 0.3 cm, and 1.0 x 0.9 x 0.3 cm. Entirely submitted.

Slide key:

E1. 2

F. LEFT TUBE AND OVARY

Labeled with patient's name, labeled "left tube and ovary", and received in formalin is a salpingo-oophorectomy specimen. The tube measures 3.5 cm in length, 0.6 cm in diameter and has fimbria at one end. The ovary is 3.0 x 1.0 x 0.6 cm. The ovary is yellow, firm with no apparent lesions. There is a 0.6 x 0.6 x 0.5 cm cyst adjacent to the fallopian tube with smooth surface, a thin wall (measuring less than 0.1 cm), filled with clear serous fluid. No other lesion identified. Entirely submitted.

Slide key:

F1, F2. Ovary and tube - 2 each

F3. Tube with adjacent cyst - 4

F4, F5. Additionally received tissue - 2, 3

G. RIGHT PERIAORTIC LYMPH NODE

Labeled with patient's name, labeled "right periaortic lymph node", and received in formalin are three portions of fibrofatty tissue ranging from 0.9 to 1.7 cm, aggregating to 3.0 x 1.5 x 0.6 cm. One tan-pink firm lymph node measuring 0.6 x 0.5 x 0.3 cm identified. Entirely submitted.

Slide key:

G1. 3

H. UTERUS AND CERVIX

Labeled with patient's name, labeled "uterus and cervix", and received in formalin is a 79 gram unopened uterus with cervix. The uterus measures 4.5 x 4.5 x 3.0 cm. The exocervix measures 4.0 x 3.5 cm, and the endocervix measures 2.5 x 2.5 cm. The external os measures 0.6 cm. The endometrial cavity measures 2.5 x 2.4 cm and has focal areas of hemorrhage on the surface. The myometrium measures 1.0 to 1.5 cm in thickness and is unremarkable. Representative sections submitted.

Slide key:

H1. Anterior cervix - 2

H2. Posterior cervix - 3

H3, H4. Anterior endometrium - 2, 3

H5, H6. Posterior endometrium - 3, 2

[page 4 of 4]
I. RIGHT PELVIC LYMPH NODE

Labeled with patient's name, labeled "right pelvic lymph node", and received in formalin are three portions of fibrofatty tissue ranging from 0.5 to 2.0 cm, and aggregating to 3.0 x 1.2 x 0.3 cm. Entirely submitted.

Slide key:

I1. 3

J. OMENTUM PART 1

Labeled with patient's name, labeled "omentum part 1", and received in formalin is a 16.0 x 8.0 x 1.9 cm portion of grossly unremarkable omentum. Representative section submitted.

Slide key:

J1. 3

K. OMENTUM PART 2

Labeled with patient's name, labeled "omentum part 2", and received in formalin is a 22.0 x 10.5 x 1.2 cm portion of grossly unremarkable omentum. Representative section submitted.

Slide key:

K1. 3

L. OMENTUM PART 3

Labeled with patient's name, labeled "omentum part 3", and received in formalin is a 14.0 x 8.0 x 3.0 cm portion of omentum. Surface of the omentum is covered by few areas of hemorrhage and irregularity (cassette L1 and L2). Representative section submitted.

Slide key:

L1, L2. Multiple each

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN):

SPECIMEN A: OVARY, RIGHT (FROZEN):

- Primary ovarian carcinoma, high grade, with some serous features

A small representative portion of ovarian tumor also released to [redacted] for research purposes

Source: NCI Genomic Data Commons file 95bdee48-ed89-440b-80e9-6769cee743c8 (TCGA-23-1809.F69B3ABA-61DF-4FD8-94D7-9BB80692464C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).